Somatic mutation profile of tumor specimen MBCProject_0644_T1A_WES (aliquot MBCProject_0644_T1A_WES_1) from CMI case MBCProject_0644, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 69.5 years (25,368 days).
Specimen MBCProject_0644_T1A_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cad0af6-3047-490b-941b-367509b09704.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0644_SALIVA (Saliva), aliquot MBCProject_0644_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5387a3a-a1bd-4588-a71c-1ddaae3bc550

The open-access MAF lists 72 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Intron 12, Silent 10, Nonsense Mutation 4, Frame Shift Del 4, 3'UTR 2, 5'Flank 2, Frame Shift Ins 1, Splice Region 1, In Frame Del 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYC1 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777042, CM137217; ClinVar: pathogenic; called by mutect2, varscan2
- GNAQ | c.286A>T p.T96S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs753716491, COSV54106107; called by muse, mutect2
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by mutect2, varscan2
- ABCC1 | c.2167C>T p.R723* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as rs760898018; called by mutect2, varscan2
- CCDC40 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs541366157; called by mutect2, varscan2
- DSP | c.7078G>A p.E2360K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.603); catalogued as COSV65793923; called by muse, mutect2
- EGFLAM | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs745930197, COSV59310512; called by mutect2, varscan2
- FAM228A | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs372181598; called by mutect2, varscan2
- FOXR1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as rs1389022175; called by mutect2, varscan2
- GLB1L | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs1364242442; called by mutect2, varscan2
- GPI | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as rs774900721; called by mutect2, varscan2
- GRIN3B | c.3008G>T p.R1003L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs557021822; called by mutect2, varscan2
- HINFP | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780798872, COSV63431617; called by mutect2, varscan2
- HK1 | c.2077G>A p.V693M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as rs749520125; called by mutect2, varscan2
- MKI67 | c.5143G>A p.E1715K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746950894, COSV64077454; called by mutect2, varscan2
- PCDH9 | c.2498C>T p.T833I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs200554725; called by mutect2, varscan2
- RANBP3 | c.1672G>A p.E558K (on ENST00000340578 / NM_007322.3; = p.E553K on NM_003624.3) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.164); catalogued as rs377345691; called by mutect2, varscan2
- SCML4 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as rs773253589, COSV64637581; called by mutect2, varscan2
- SH3BP2 | c.823del p.R275Efs*3 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs776466609, COSV62555238; called by mutect2, varscan2
- SIN3A | c.2151G>A p.W717* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100845226; called by mutect2, varscan2
- SLC22A1 | c.1385G>A p.R462K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1422280676; called by mutect2, varscan2
- STK36 | c.3334C>T p.R1112W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs748829998, COSV99830842; called by mutect2, varscan2
- SYNJ2 | c.3845G>A p.R1282Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs763382477; called by mutect2, varscan2
- TFAP2B | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53831516; called by mutect2, varscan2
- TOPBP1 | c.2638C>T p.R880* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV53435638; called by mutect2, varscan2
- WDR62 | c.2317C>T p.R773W | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1037491343, COSV54334831; called by mutect2, varscan2
- ZDHHC17 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100602183; called by mutect2, varscan2
- ABCC6 | c.1580C>T p.T527I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); called by mutect2, varscan2
- ABCC8 | c.742_771del p.I250_A259del | In Frame Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- CCDC93 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.467); called by muse, varscan2
- CTCFL | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- FRMPD3 | c.1290del p.N431Tfs*40 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, varscan2
- ILK | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); called by mutect2, varscan2
- KMT2C | c.10751del p.G3584Dfs*13 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.3061dup p.T1021Nfs*15 | Frame Shift Ins (INS) | VAF 8/69 reads (12%) | called by mutect2, pindel, varscan2
- MRPL24 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2
- PARP4 | c.4773A>C p.E1591D | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.096); called by muse, varscan2
- PRPH2 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, varscan2
- PRRC2A | c.5542-6C>T | Splice Region (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- SBK3 | c.1065_*12del | Nonstop Mutation (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- TTC33 | c.165_186del p.C55* | Frame Shift Del (DEL) | VAF 4/61 reads (7%) | called by mutect2, pindel
- ZMIZ1 | c.2771C>T p.P924L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); called by mutect2, varscan2
- ZNF71 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- ZNF862 | c.1062G>T p.Q354H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ACOX2 | c.180C>T p.Y60= | Silent (SNP) | VAF 5/33 reads (15%) | called by mutect2, varscan2
- MEX3D | c.990G>A p.A330= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs1470098462; called by mutect2, varscan2
- PDP1 | c.111G>A p.S37= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs761727112, COSV52602412; called by mutect2, varscan2
- PKD1 | c.3876C>T p.F1292= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs569009244, COSV51914148; called by mutect2, varscan2
- PRICKLE3 | c.1050C>T p.G350= | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- RANBP10 | c.453C>T p.C151= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1567683125; called by mutect2, varscan2
- SSRP1 | c.1758G>A p.K586= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs61756192; called by mutect2, varscan2
- TENM2 | c.8253G>A p.E2751= (on ENST00000518659 / NM_001122679.2; = p.E2512= on NM_001080428.3) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs777360997; called by mutect2, varscan2
- TRIM75P | c.501A>G p.K167= | Silent (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- ZNF443 | c.768A>G p.K256= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs879182769, COSV56894514; called by muse, varscan2
- ADGRA1 | c.256-433T>C | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as rs1286961331; called by muse, varscan2
- C8orf44-SGK3 | c.-481-1859A>G | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs1440237050, COSV66402151; called by mutect2, varscan2
- CCDC198 | c.656-4078A>G | Intron (SNP) | VAF 6/28 reads (21%) | catalogued as rs1303405509; called by mutect2, varscan2
- CMTM1 | c.81+175C>T | Intron (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- DDIAS | chr11:82913986 A>G | 5'Flank (SNP) | VAF 5/28 reads (18%) | catalogued as rs1386717589; called by mutect2, varscan2
- LINC01549 | n.373A>G | RNA (SNP) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- LNPK | c.707-1350T>C | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, varscan2
- LY9 | c.454+1812C>T | Intron (SNP) | VAF 5/29 reads (17%) | catalogued as rs771524372, COSV54436037; called by mutect2, varscan2
- MCM2 | c.1428+1775C>T | Intron (SNP) | VAF 4/27 reads (15%) | catalogued as COSV54032394; called by mutect2, varscan2
- METTL5 | c.591+106A>G | Intron (SNP) | VAF 5/40 reads (13%) | catalogued as rs1292649547, COSV53627506; called by muse, varscan2
- RN7SL484P | chr15:99790247 A>C | 5'Flank (SNP) | VAF 5/17 reads (29%) | catalogued as rs760293692; called by mutect2, varscan2
- RNF170 | c.*680T>C | 3'UTR (SNP) | VAF 7/31 reads (23%) | catalogued as rs1334006713; called by muse, varscan2
- SMTN | c.-19G>A | 5'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs747955183; called by mutect2, varscan2
- TRIP6 | c.999+360T>G | Intron (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- USP4 | c.696-901T>C | Intron (SNP) | VAF 8/40 reads (20%) | catalogued as rs1227647101, COSV55535256; called by muse, varscan2
- XIAP | c.*4034T>C | 3'UTR (SNP) | VAF 4/27 reads (15%) | catalogued as rs1175421431; called by mutect2, varscan2
- YIPF3 | c.395+329G>T | Intron (SNP) | VAF 13/86 reads (15%) | catalogued as rs1383044718, COSV104411955; called by muse, varscan2
- ZNF684 | c.239-2098A>G | Intron (SNP) | VAF 4/31 reads (13%) | catalogued as rs1388266370; called by muse, varscan2
